Somatic mutation profile of tumor specimen 0DII4A from CCDI case PBBVKT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 11.1 years (4,066 days).
Specimen 0DII4A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30cb5d77-390c-4160-93b4-f515a0e0f40a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DII35 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4e3e3fb-4294-459d-8dcc-f9a91c12358f

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, Nonsense Mutation 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A4GALT | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1279378344; called by muse, mutect2
- APOBR | c.2908G>A p.A970T (on ENST00000431282; = p.A979T on NM_018690.4) | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1422432818; called by muse, mutect2
- GPR63 | c.161C>G p.T54S | Missense Mutation (SNP) | VAF 20/672 reads (3%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1021708743; called by muse, mutect2
- LAMB3 | c.2912G>A p.S971N | Missense Mutation (SNP) | VAF 185/465 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201448367, COSV50522003; called by muse, mutect2, varscan2
- MICAL3 | c.4097A>G p.Y1366C | Missense Mutation (SNP) | VAF 249/537 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs779216648; called by muse, mutect2, varscan2
- PCDH10 | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 188/435 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV52100555; called by muse, mutect2, varscan2
- DLC1 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 77/539 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- DMD | c.7882A>G p.K2628E | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.06); called by muse, mutect2
- RBP7 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 203/579 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TMED3 | c.418-2A>G p.X140_splice | Splice Site (SNP) | VAF 31/528 reads (6%) | called by muse, mutect2
- USP48 | c.1491G>A p.W497* | Nonsense Mutation (SNP) | VAF 175/377 reads (46%) | called by muse, mutect2, varscan2
- CAMTA2 | c.1785G>A p.V595= | Silent (SNP) | VAF 18/548 reads (3%) | called by muse, mutect2
- CDR2L | c.492G>A p.L164= | Silent (SNP) | VAF 54/510 reads (11%) | called by muse, mutect2, varscan2
- CIAO3 | c.1203C>T p.N401= | Silent (SNP) | VAF 139/402 reads (35%) | catalogued as rs767440685; called by muse, mutect2, varscan2
- PPIG | c.377+19A>G | Intron (SNP) | VAF 35/541 reads (6%) | called by muse, mutect2
- TEN1 | c.*21C>A | 3'UTR (SNP) | VAF 24/354 reads (7%) | called by muse, mutect2
- TGM4 | c.972-63G>A | Intron (SNP) | VAF 18/241 reads (7%) | catalogued as rs1032790463; called by muse, mutect2
